Somatic mutation profile of tumor specimen TCGA-XM-AAZ1-01A (aliquot TCGA-XM-AAZ1-01A-11D-A423-09) from TCGA case TCGA-XM-AAZ1, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 42.1 years (15,383 days).
Specimen TCGA-XM-AAZ1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d173e54f-dd1f-4a96-856f-8ac23d7161da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-AAZ1-10A (Blood Derived Normal), aliquot TCGA-XM-AAZ1-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6e4f08-4ee4-4c37-8998-3704393805c4

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV65451243, COSV65451791; called by muse, mutect2, varscan2
- NRAS | c.48A>C p.K16N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54742418; called by muse, mutect2, varscan2
- RNF146 | c.804A>T p.E268D (on ENST00000368314 / NM_001242850.2; = p.E267D on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.967); catalogued as rs756825211, COSV58933300; called by mutect2, varscan2
- SLC29A1 | c.1102C>G p.R368G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751747928, COSV57580676; called by muse, mutect2, varscan2
- TNFRSF11B | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs773538970, COSV52069574; called by muse, mutect2, varscan2
- ARHGEF28 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RASA1 | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
